Somatic mutation profile of tumor specimen TCGA-MP-A4T9-01A (aliquot TCGA-MP-A4T9-01A-11D-A24P-08) from TCGA case TCGA-MP-A4T9, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.1 years (19,767 days).
Specimen TCGA-MP-A4T9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d866327c-a734-4386-b4ca-7a30353baaa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4T9-10A (Blood Derived Normal), aliquot TCGA-MP-A4T9-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f90c03c-96f5-47dc-85fa-279c634b257e

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Nonsense Mutation 2, 3'Flank 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 62/219 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993G>A p.Q331= | Splice Region (SNP) | VAF 13/90 reads (14%) | catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.1824C>A p.Y608* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99795943; called by muse, mutect2
- C1orf52 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99641037; called by muse, mutect2, varscan2
- CIAO1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99302670; called by muse, mutect2, varscan2
- CIAO2B | c.157A>T p.I53F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100399300; called by muse, mutect2
- DLX5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 9/142 reads (6%) | catalogued as COSV56033490; called by muse, mutect2
- DNAH7 | c.7204C>G p.Q2402E | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414436, COSV100415991; called by muse, mutect2
- GPR119 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV99358671; called by muse, mutect2
- GRIN2A | c.3341G>C p.R1114T | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as rs1555482504, COSV58022882, COSV58027558; called by muse, mutect2
- HSF2 | c.1468A>G p.S490G | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100869689; called by muse, mutect2, varscan2
- HTATSF1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV99511742; called by muse, mutect2
- IL3RA | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100452334; called by muse, mutect2
- MARK1 | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65069442; called by muse, mutect2
- MDM2 | c.868G>T p.G290W | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99254693; called by muse, mutect2
- NBAS | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318558966, COSV99870477; called by muse, mutect2, varscan2
- PCNT | c.8534C>T p.S2845L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1056616069, COSV64032813; called by muse, mutect2
- SERPINI1 | c.785T>A p.V262D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99855169; called by muse, mutect2
- SLC25A24 | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV99916380; called by muse, mutect2, varscan2
- SYNPO | c.2557C>T p.P853S (on ENST00000394243 / NM_001166208.2; = p.P609S on NM_007286.6) | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV99059833; called by muse, mutect2
- TFE3 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100252646; called by muse, mutect2, varscan2
- VIPAS39 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.096); catalogued as rs188151618; ClinVar: uncertain significance; called by muse, mutect2
- VWC2 | c.915G>C p.E305D | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.525); catalogued as COSV100514426; called by muse, mutect2
- ZNF212 | c.1169G>C p.C390S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100242396; called by muse, mutect2
- LTB4R | c.121_147del p.W41_K49del | In Frame Del (DEL) | VAF 22/262 reads (8%) | called by mutect2, pindel
- AFF1 | c.963C>T p.T321= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs1167601748, COSV100320801; called by muse, mutect2
- ANK2 | c.5616G>A p.S1872= | Silent (SNP) | VAF 23/222 reads (10%) | catalogued as rs761557717, COSV52190412; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARFGEF2 | c.1215G>A p.V405= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1372980842, COSV100904335; called by muse, mutect2, varscan2
- CCDC114 | c.723G>T p.L241= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV100196875; called by muse, mutect2, varscan2
- GDF3 | c.627T>C p.D209= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs764686808, COSV100325324; called by muse, mutect2, varscan2
- GP2 | c.75G>A p.Q25= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs531475464, COSV100221484; called by muse, mutect2, varscan2
- NSD2 | c.3186C>T p.Y1062= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV100373574; called by muse, mutect2
- PCDHGA8 | c.87A>G p.G29= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV99537679; called by muse, mutect2
- SLC12A7 | c.2919G>A p.T973= | Silent (SNP) | VAF 15/237 reads (6%) | catalogued as rs368202348; called by muse, mutect2
- TFAP2B | c.891G>A p.A297= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as rs774712715, COSV99540438; called by muse, mutect2, varscan2
- FAM153CP | chr5:178055783 G>A | 3'Flank (SNP) | VAF 8/106 reads (8%) | catalogued as rs1334732968; called by muse, mutect2
